Somatic mutation profile of tumor specimen TCGA-13-0894-01B (aliquot TCGA-13-0894-01B-01W-0494-09) from TCGA case TCGA-13-0894, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 53.3 years (19,466 days).
Specimen TCGA-13-0894-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 863002ca-5f3a-4a04-a35f-d1ac16fd1a52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0894-10A (Blood Derived Normal), aliquot TCGA-13-0894-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95e0ad28-18d2-4122-b12a-d56a4cc07dcc

The open-access MAF lists 81 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 17, Nonsense Mutation 4, Splice Site 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1662C>A p.D554E | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52706246; called by muse, mutect2, varscan2
- ABCG4 | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs1385693209, COSV100266698; called by muse, mutect2, varscan2
- ADAMTS8 | c.2544C>A p.C848* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV57296303, COSV99960750; called by muse, mutect2, varscan2
- ADGRG6 | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV51591081; called by muse, mutect2, varscan2
- ANKRD24 | c.3434G>T p.G1145V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99517363; called by muse, mutect2
- ATAD5 | c.4403T>G p.I1468S | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV58974063; called by muse, mutect2, varscan2
- ATPAF2 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV100572705; called by muse, mutect2, varscan2
- BRINP2 | c.2033T>G p.M678R | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100838034; called by muse, mutect2, varscan2
- C14orf39 | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as rs1429265123, COSV58781516; called by muse, mutect2, varscan2
- CENPF | c.7587T>G p.N2529K | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV65274620; called by muse, mutect2, varscan2
- CGNL1 | c.1463G>A p.G488D | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV55567111; called by muse, mutect2, varscan2
- CHMP4C | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926958; called by muse, mutect2, varscan2
- CRB1 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.241); catalogued as rs1199892094, COSV66340025; called by muse, varscan2
- CRYBB1 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 10/254 reads (4%) | catalogued as COSV53234238, COSV99315963; called by muse, mutect2
- CYP7B1 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 52/793 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100041409; called by muse, mutect2
- DMXL1 | c.8054T>C p.I2685T | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs920039141, COSV100223781; called by muse, mutect2, varscan2
- DYNC1I2 | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.194); catalogued as COSV55525686; called by muse, mutect2, varscan2
- EFR3A | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as COSV54456391; called by muse, mutect2, varscan2
- EHHADH | c.2160C>G p.S720R | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51629860; called by muse, mutect2, varscan2
- FARSA | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765172401, COSV53367504; called by muse, mutect2, varscan2
- FCHSD2 | c.353C>A p.T118K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV60806028; called by muse, mutect2
- FNDC3B | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV100394012; called by muse, mutect2
- GABRA6 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV50877559; called by muse, mutect2, varscan2
- GFRAL | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 129/817 reads (16%) | catalogued as COSV61228659; called by muse, varscan2
- GFRAL | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 70/438 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100475013; called by muse, varscan2
- GOLGA4 | c.3641C>G p.A1214G | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as COSV62710470; called by muse, mutect2, varscan2
- GPNMB | c.1141A>G p.I381V (on ENST00000381990 / NM_001005340.2; = p.I369V on NM_002510.3) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV99326442; called by muse, mutect2
- GTDC1 | c.738G>C p.L246F | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV53989096; called by muse, mutect2, varscan2
- IGF2BP3 | c.542G>T p.R181M | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV51683753, COSV51694098; called by muse, mutect2, varscan2
- ILVBL | c.524T>A p.F175Y | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV54619347; called by muse, mutect2, varscan2
- IVNS1ABP | c.96T>A p.C32* | Nonsense Mutation (SNP) | VAF 52/163 reads (32%) | catalogued as COSV62249982; called by muse, mutect2, varscan2
- L3MBTL3 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs940968246, COSV62385915; called by muse, mutect2, varscan2
- MAP4K3 | c.2379T>C p.C793= | Splice Region (SNP) | VAF 8/75 reads (11%) | catalogued as COSV55712529; called by muse, mutect2
- OPN5 | c.756+1G>C p.X252_splice | Splice Site (SNP) | VAF 54/276 reads (20%) | catalogued as COSV55245315; called by muse, varscan2
- OR11H6 | c.9T>G p.F3L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV59644121; called by muse, mutect2, varscan2
- OR2A12 | c.790A>G p.S264G | Missense Mutation (SNP) | VAF 77/753 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.158); catalogued as COSV68821359; called by muse, mutect2, varscan2
- OR2T33 | c.951C>A p.H317Q | Missense Mutation (SNP) | VAF 64/417 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV58815178; called by muse, mutect2, varscan2
- PEG3 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 86/482 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs146466276; called by muse, mutect2, varscan2
- PKD1L1 | c.5444A>G p.K1815R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV99219333; called by muse, mutect2
- PKHD1L1 | c.4061G>C p.G1354A | Missense Mutation (SNP) | VAF 47/374 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65742098; called by muse, mutect2, varscan2
- PLXNA2 | c.866A>T p.K289M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV104424163, COSV65440190; called by muse, mutect2, varscan2
- PNLIPRP1 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 102/298 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62611666; called by muse, mutect2, varscan2
- POLQ | c.1831C>G p.P611A | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV51750700; called by muse, mutect2, varscan2
- PPARA | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.08); catalogued as COSV53078262; called by muse, mutect2, varscan2
- PPP2R3C | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs914955161, COSV54832489; called by muse, mutect2, varscan2
- PTCD1 | c.387G>T p.W129C | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV52857383; called by muse, mutect2, varscan2
- R3HDM2 | c.2354T>A p.L785H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1301004452, COSV61288145; called by muse, mutect2, varscan2
- RASSF2 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65082062; called by muse, mutect2
- RHOD | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV100448062; called by muse, mutect2
- SAFB | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs753148563, COSV52651136; called by muse, mutect2, varscan2
- SLC9A7 | c.2072C>T p.T691M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs371727694, COSV60378793; called by muse, mutect2, varscan2
- STYXL2 | c.1631T>A p.L544Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54804616; called by muse, mutect2, varscan2
- SYT10 | c.152-2A>G p.X51_splice | Splice Site (SNP) | VAF 32/118 reads (27%) | catalogued as COSV57339899; called by muse, mutect2, varscan2
- TFB2M | c.1160G>C p.W387S | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63624914; called by muse, mutect2, varscan2
- TRIM67 | c.1879A>G p.N627D | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV64158734; called by muse, mutect2, varscan2
- TRPC3 | c.1142G>C p.R381P (on ENST00000379645 / NM_001366479.2; = p.R308P on NM_003305.2) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53374898, COSV53375138; called by muse, mutect2, varscan2
- TSC22D1 | c.2993C>T p.A998V (on ENST00000458659 / NM_183422.4; = p.A69V on NM_006022.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779260235, COSV54925451; called by mutect2, varscan2
- WWC1 | c.1324C>A p.L442I | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99514804; called by muse, mutect2
- ZNF561 | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 137/696 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as COSV57177652; called by muse, mutect2, varscan2
- NHEJ1 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); called by muse, mutect2
- POGLUT1 | c.309G>T p.M103I | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- SNX21 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- ADGRV1 | c.11220C>A p.T3740= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as COSV67984258; called by muse, mutect2, varscan2
- CD36 | c.1374T>C p.A458= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV59210410, COSV59212593; called by muse, mutect2, varscan2
- CFAP65 | c.2160T>G p.P720= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV58560075, COSV58560507; called by muse, mutect2, varscan2
- CXCL2 | c.210C>T p.A70= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1381776427, COSV99933196; called by muse, mutect2, varscan2
- CYP1A1 | c.183G>A p.L61= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV101122275; called by muse, mutect2, varscan2
- FAM171A1 | c.1215C>A p.G405= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV65315128; called by muse, varscan2
- GFM1 | c.928T>C p.L310= | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as rs1188969241, COSV51832433; called by muse, mutect2, varscan2
- GJB1 | c.177C>T p.G59= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100661263; called by muse, mutect2
- NLRP7 | c.1824C>G p.S608= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100052345; called by muse, mutect2
- OAT | c.531C>T p.F177= | Silent (SNP) | VAF 16/163 reads (10%) | catalogued as COSV100920416; called by muse, mutect2
- PPM1G | c.1230C>T p.N410= | Silent (SNP) | VAF 80/152 reads (53%) | catalogued as COSV59769331; called by muse, mutect2, varscan2
- ROBO4 | c.843G>T p.T281= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs138055137, COSV100127510; called by muse, mutect2, varscan2
- SPAM1 | c.1461C>T p.S487= | Silent (SNP) | VAF 42/363 reads (12%) | catalogued as COSV56143188; called by muse, mutect2, varscan2
- TLR8 | c.1536G>T p.L512= (on ENST00000218032 / NM_138636.5; = p.L530= on NM_016610.4) | Silent (SNP) | VAF 48/203 reads (24%) | catalogued as COSV54317664; called by muse, mutect2, varscan2
- TRAV19 | c.165C>T p.F55= | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- ZNF248 | c.180C>T p.I60= | Silent (SNP) | VAF 77/332 reads (23%) | catalogued as rs1320031869, COSV61997609; called by muse, mutect2, varscan2
- ZNF256 | c.1551G>A p.R517= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as rs781008432, COSV99990774; called by muse, mutect2
- CEP112 | c.2394+25521G>T | Intron (SNP) | VAF 68/680 reads (10%) | catalogued as COSV100439092; called by muse, mutect2, varscan2
